Gene-level copy-number profile of tumor specimen TCGA-VR-A8EP-01A from TCGA case TCGA-VR-A8EP, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 51.9 years (18,942 days).
Specimen TCGA-VR-A8EP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.392c69d4-34ed-478b-8cb7-f119cb3ff36d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VR-A8EP-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/af3cc09f-f12a-46ae-9758-b478a084e29e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 123; copy number 1: 21,717; copy number 2: 33,841; copy number 3: 2,974; copy number 4: 887; copy number 5: 35; copy number 6: 58; copy number 8: 32; copy number 11: 30; copy number 14: 3; copy number 16: 93; copy number 17: 7; copy number 18: 6; copy number 19: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VR-A8EP-01A-31D-A402-01): tumor purity 0.44, ploidy 3.12, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 123 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:59,747,277–61,251,459, 1 gene (within-gene range 0–1): FHIT.
- chr3:60,616,822–62,374,324, 14 genes: AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71, U3, PTPRG, Y_RNA, RPL10AP6, RNU2-10P, ID2B, PTPRG-AS1, C3orf14, FEZF2.
- chr4:157,568,731–162,164,004, 46 genes (within-gene range 0–1): AC093817.2, LINC02433, AC093817.1, Y_RNA, AC017037.1, AC017037.3, AC017037.5, AC084740.1, AC017037.4, AC017037.2, AC098679.2, AC098679.3, GASK1B, FAM198B-AS1, AC098679.5, NUDT19P5, AC098679.1, TMEM144, AC098679.4, AIDAP2, RXFP1, RNU4-79P, AC121161.1, AC121161.2, C4orf46, ETFDH, U3, PPID, FNIP2, RNU6-128P, C4orf45, SNORD39, PSME2P3, FABP5P12, Y_RNA, RAPGEF2, MIR3688-1, MIR3688-2, AC074344.1, AC074344.2, LINC02233, AC093853.1, LINC02477, RPS14P7, AC104793.1, FSTL5.
- chr5:98,338,744–103,033,031, 61 genes (broad region; genes not listed).
- chr13:71,704,181–71,704,655, 1 gene: RPL21P109.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 269 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:36,768,122–41,242,154, 144 genes, copy number 8–16 (within-gene range 2–16) (broad region; genes not listed).
- chr2:7,922,425–8,278,186, 1 gene, copy number 6 (within-gene range 4–6): LINC00298.
- chr2:7,988,683–10,689,987, 55 genes, copy number 5–6 (within-gene range 2–6): LINC00299, U91324.1, LINC01814, AC092617.1, AC011747.1, SNRPEP5, ID2-AS1, ID2, KIDINS220, MBOAT2, HMGB1P25, RPL30P3, AC093904.2, AC093904.4, AC093904.3, AC093904.1, ASAP2, EIF1P7, ITGB1BP1, CPSF3, IAH1, ADAM17, AC080162.1, AC073195.1, YWHAQ, Y_RNA, AC082651.1, AC082651.4, RNU4-73P, AC082651.2, AC082651.3, TAF1B, AC010969.2, AC010969.3, GRHL1, AC010969.1, AC104794.4, AC104794.3, KLF11, AC104794.5, CYS1, AC104794.2, AC104794.1, RRM2, AC007240.1, MIR4261, RN7SL66P, AC007240.3, AC007240.2, HPCAL1, ODC1, SNORA80B, ODC1-DT, NOL10, AC007314.1.
- chr3:180,868,141–182,052,270, 21 genes, copy number 5–18: FXR1, AC108734.1, DNAJC19, SOX2-OT, AC083904.1, RNU6-4P, FAUP2, AC068308.1, RPL7AP25, AC125613.1, AC125613.2, AC117415.1, SOX2, AC117415.2, RN7SL703P, RNA5SP150, AC007547.2, AC007547.1, LINC01206, RN7SKP265, AC012081.2.
- chr6:133,952,170–133,990,432, 1 gene, copy number 5 (within-gene range 2–5): TBPL1.
- chr6:133,987,581–134,707,349, 19 genes, copy number 5–17: SLC2A12, AL449363.1, AL449363.2, HMGA1P7, RN7SL408P, SGK1, RNA5SP218, Y_RNA, AL355881.1, KRT8P42, LINC01010, Z84486.1, CHCHD2P4, CT69, AL078590.2, FAM8A6P, AL078590.1, AL596188.1, AL121970.1.
- chr9:16,917,511–18,910,950, 14 genes, copy number 11–19: AL162725.2, AL358117.1, RN7SL720P, RPS29P33, AL162725.1, CNTLN, SAMM50P1, SH3GL2, PABPC1P11, ADAMTSL1, AL442638.1, MIR3152, RN7SKP258, RAP1BP1.
- chr10:5,035,354–5,107,686, 2 genes, copy number 5: AKR1C3, U8.
- chr11:20,363,685–21,575,686, 8 genes, copy number 6 (within-gene range 2–6): HTATIP2, PRMT3, HMGB1P40, AC090707.2, SLC6A5, NELL1, AC090707.1, RNA5SP336.
- chr15:47,774,219–48,050,507, 4 genes, copy number 6 (within-gene range 2–6): LINC01491, AC092078.2, AC092078.1, AC092078.3.

Autosomal genes at a single copy (total copy number 1): 19,296. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
